Gene-level copy-number profile of tumor specimen TCGA-3A-A9I9-01A from TCGA case TCGA-3A-A9I9, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 67.7 years (24,731 days).
Specimen TCGA-3A-A9I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.37ae8369-68bb-4072-9640-468e9f0406b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3A-A9I9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/51332979-d7fa-4584-9f85-034479cc757e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 322; copy number 1: 20,505; copy number 2: 34,236; copy number 3: 4,361; copy number 4: 376; copy number 5: 14; copy number 6: 1; copy number 7: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3A-A9I9-01A-11D-A38F-01): tumor purity 0.32, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 315 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–2,701,812, 43 genes: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1, AC018685.2, AC018685.3.
- chr8:150,584–2,926,689, 57 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1.
- chr8:6,044,353–6,789,021, 13 genes (within-gene range 0–1): AC009435.1, AC016065.1, MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055, AGPAT5, MIR4659A, MIR4659B, AF233439.2.
- chr9:16,726,814–17,503,923, 9 genes: BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1.
- chr10:36,432,882–36,995,585, 9 genes: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2.
- chr12:30,926,428–32,896,777, 70 genes (within-gene range 0–1) (broad region; genes not listed).
- chr18:74,597,870–80,247,514, 114 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,143,367–10,295,579, 10 genes, copy number 5: AC093664.1, AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,157,207–77,433,388, 4 genes, copy number 5 (within-gene range 2–5): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr8:139,096,305–139,127,953, 3 genes, copy number 7: AC027541.1, AC100807.1, AC100807.2.
- chr9:109,760,360–109,772,043, 1 gene, copy number 6 (within-gene range 2–6): AL158829.1.
- chr16:52,198,012–52,227,956, 1 gene, copy number 7 (within-gene range 2–7): AC007333.2.

Autosomal genes at a single copy (total copy number 1): 18,421. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
